Surgical pathology report (de-identified scan), TCGA case TCGA-FV-A3I0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FV-A3I0-01A (Primary Tumor).

[page 1 of 3]
Results History

GROSS AND MICROSCOPIC SURGICAL PANEL

Entry Information

Entry Date and Time

Lab Status

Entered by

Final result

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

LAB:

Phone:

Fax

Final Report

DIAGNOSIS

A) LIVER, SEGMENT 3, BIOPSY:

1. Normal liver
2. No evidence of malignancy

B) GALLBLADDER, RESECTION:

1. Mild chronic cholecystitis
2. No cholelithiasis
3. No evidence of dysplasia or malignancy

HIIPAA Discrepancy		X
Reviewed by:	KM1	12/1/11

C) LIVER, RIGHT LOBE, LAPAROSCOPIC HAND-ASSISTED RIGHT HEPATIC LOBECTOMY (SEGMENTS 5, 6, 7 AND 8):

1. Intrahepatic cholangiocarcinoma characterized by:
- a. 12 cm lesion with 12 intrahepatic metastatic foci (range from 0.5-2 cm)
- b. Moderately differentiated
- c. Margins: Negative (2 cm from bile duct margin and 2 cm from the nearest hepatic resection margin)
2. Background liver with reactive changes but no evidence of primary chronic liver disease
3. Please see staging parameters

2010 INTRAHEPATIC BILE DUCT CANCER STAGING PARAMETERS

Final TNM: pT2aNXM0

2010 stage: II

ICD-0-3

Path: Cholangiocarcinoma 8160/3

COEF: Cholangiocarcinoma and hepatocellular carcinoma, combined 8180/3

Site: Liver c22.0

MACROSCOPIC SPECIMEN TYPE

Lobectomy

TUMOR TYPE

Single with satellites

TUMOR SIZE

Single tumor measuring 12 X X cm, with 12 satellite tumor(s) measuring 0.5-2.0 cm

pw
12/2/11

MICROSCOPIC

HISTOLOGIC TYPE

Intrahepatic cholangiocarcinoma, mass forming tumor growth pattern

HISTOLOGIC GRADE

Grade 2 of 4 Moderately differentiated

MARGINS

Uninvolved by tumor; Distance to nearest margin is 2 cm

LIVER CAPSULE

[page 2 of 3]
No tumor present
LYMPHATIC/VASCULAR INVASION
Present: Lymph-vascular invasion present/Identified

PATHOLOGIC STAGING

EXTENT OF INVASION

pT2a. (Solitary tumor with vascular invasion)

REGIONAL LYMPH NODES

pNX. (Cannot be assessed)

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT2aNXM0

2010 stage: II

* The pathologic stage presumes no lymph node metastasis.

** The pathologic stage presumes no distant metastasis.

PROGNOSTIC FACTORS (SITE SPECIFIC) AND ANCILLARY STUDIES

CIRRHOSIS

Absent

PRIMARY SCLEROSING CHOLANGITIS

Absent

CLINICAL INFORMATION

History of cholangiocarcinoma

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Liver segment 3

The specimen is received fresh from the OR labeled "liver segment 3" and consists of a 0.5 x 0.5 x 0.1 cm discoid tan-brown tissue which is bisected and entirely frozen on one block.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "No evidence of malignancy" is [REDACTED]

B) SOURCE: Gallbladder

Labeled "gallbladder" is a pink-purple, 7 x 2.5 x 2 cm gallbladder. The serosal surface is smooth and glistening. The cystic duct is identified with a 0.2 cm luminal diameter. The specimen is opened revealing a tan-green, velvety mucosa with multiple yellow flecks consistent with cholesterosis. The average wall thickness is 0.1 cm. No calculi are grossly identified. Multiple representative sections of gallbladder wall and en face cystic duct margin are submitted in a single cassette.

C) SOURCE: Liver, right lobe

Labeled "right lobe liver" and received fresh from the OR is a 1198 g, 19 x 14 x 9 cm liver lobe. The liver capsule is red-brown with a 12 x 6 cm white-pink protruding area present. The resection margin is inked black.

The specimen is serially sectioned revealing multiple (approximately 12-15) white-tan firm tumor nodules ranging from 0.5-12 cm in greatest dimension. The nearest tumor nodule measures 2 cm to the bile duct margin and 2 cm to the resection margin. The remaining liver parenchyma is red-brown and

[page 3 of 3]
unremarkable.

A representative section of the bile duct margin designated by surgeon, [REDACTED] is submitted on a single chuck for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Margin identified by surgeon benign" is rendered [REDACTED]

Representative sections are submitted in 11 cassettes labeled:

- CFS1. Frozen section bile duct margin
- 2-4. Representative largest tumor to capsule
- 5. Tumor nearest resection margin (black)
- 6. Remainder of bile duct margin
- 7. Tumor to adjacent normal liver parenchyma
- 8-9. Representative smaller tumors
- 10-11. Random liver

Photographs are taken of the specimen.

Representative tissue is taken for further possible studies.

This case is accessioned in [REDACTED]

MICROSCOPIC

A-C) The microscopic appearance substantiates the diagnosis. Dictation by: [REDACTED]

Interpreted at [REDACTED]

COLLECTED: [REDACTED] ACCESSIONED: [REDACTED] SIGNED: [REDACTED]

Entry Information

Entry Date and Time	Lab Status	Entered by
[REDACTED]	In process	[REDACTED]

Entry Information

Entry Date and Time	Lab Status	Entered by
[REDACTED]	In process	[REDACTED]

Entry Information

Entry Date and Time	Lab Status	Entered by
[REDACTED]	In process	[REDACTED]

Source: NCI Genomic Data Commons file 8cf7dea4-e162-4c29-a7d7-723056d5372c (TCGA-FV-A3I0.B4DB59E9-FFBB-4716-9235-90A1DF17455B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).